Somatic mutation profile of tumor specimen TARGET-10-PARBLL-09A (aliquot TARGET-10-PARBLL-09A-01D) from TARGET case TARGET-10-PARBLL, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.4 years (1,963 days).
Specimen TARGET-10-PARBLL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8883c36-6e6b-40bf-a0b8-34f6977b579f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARBLL-10A (Blood Derived Normal), aliquot TARGET-10-PARBLL-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8018c8bd-a75f-4cff-82a7-9193b0857b0a

The open-access MAF lists 51 somatic variants for this specimen: 32 protein-altering or splice-affecting, 11 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 11, Intron 6, Splice Region 4, Nonsense Mutation 3, 5'UTR 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 24/94 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 7/55 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ZP3 | c.400G>A p.A134T (on ENST00000394857 / NM_001110354.2; = p.A83T on NM_007155.6) | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as rs1554625334, COSV60630294; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BBS12 | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as rs763538270; called by muse, varscan2
- EIF2AK3 | c.2764G>A p.A922T | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as rs774904859, COSV57550609; called by muse, mutect2, varscan2
- ENOPH1 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV56732547; called by muse, mutect2, varscan2
- HAO2 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs765518257, COSV58040369; called by muse, mutect2, varscan2
- HEPACAM2 | c.78C>T p.F26= | Splice Region (SNP) | VAF 24/40 reads (60%) | catalogued as rs1210870913; called by muse, mutect2, varscan2
- HEPH | c.3421C>T p.R1141C (on ENST00000343002; = p.R874C on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); catalogued as rs781742782, COSV57961166; called by muse, mutect2, varscan2
- LIMA1 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs761969650, COSV57968714; called by muse, mutect2, varscan2
- MFAP5 | c.96C>T p.D32= | Splice Region (SNP) | VAF 39/87 reads (45%) | catalogued as rs778394071, COSV63945493; called by muse, mutect2, varscan2
- NBEA | c.6233G>A p.R2078K | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs753679154, COSV59779633; called by muse, mutect2, varscan2
- NELFE | c.598C>T p.R200* | Nonsense Mutation (SNP) | VAF 29/81 reads (36%) | catalogued as rs1336551211; called by muse, mutect2, varscan2
- PID1 | c.514G>A p.D172N (on ENST00000354069 / NM_001330156.1; = p.D170N on NM_017933.5) | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV62475256; called by muse, mutect2, varscan2
- TRIM66 | c.408G>A p.R136= | Splice Region (SNP) | VAF 44/91 reads (48%) | catalogued as rs1463968243; called by muse, mutect2, varscan2
- BBS12 | c.1230C>A p.N410K | Missense Mutation (SNP) | VAF 64/177 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.767); called by muse, varscan2
- CLDN34 | c.31C>T p.Q11* | Nonsense Mutation (SNP) | VAF 20/50 reads (40%) | called by muse, mutect2, varscan2
- ELP1 | c.2921C>T p.A974V | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- FRRS1 | c.374A>T p.E125V | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- GCLC | c.1759C>T p.P587S (on ENST00000643939; = p.P585S on NM_001498.4) | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- HCRTR2 | c.656A>T p.Y219F | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- KIF21A | c.1058G>A p.R353K | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- KMT2D | c.11133_11137dup p.S3713Lfs*38 | Frame Shift Ins (INS) | VAF 41/88 reads (47%) | called by mutect2, pindel, varscan2
- METTL21C | c.703G>C p.D235H | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- NID1 | c.2920C>T p.H974Y | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PLD5 | c.735G>A p.Q245= (on ENST00000442594; = p.Q183= on NM_001195811.1 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 17/37 reads (46%) | called by muse, mutect2, varscan2
- PSD | c.2854_2855insGAAGGT p.R951_Y952ins* | Nonsense Mutation (INS) | VAF 24/43 reads (56%) | called by mutect2, pindel, varscan2
- SEC14L2 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- SLC5A4 | c.1784C>T p.S595L | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- THBS2 | c.322C>T p.L108F | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TTC24 | c.1374A>C p.E458D | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- ZNF217 | c.724dup p.T242Nfs*37 | Frame Shift Ins (INS) | VAF 34/64 reads (53%) | called by mutect2, varscan2
- ADAM22 | c.2271G>A p.A757= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as rs375592711; called by muse, mutect2, varscan2
- AL645922.1 | c.1974G>A p.A658= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as rs1318682750, COSV100190992; called by muse, mutect2, varscan2
- CCDC158 | c.957C>T p.L319= | Silent (SNP) | VAF 58/222 reads (26%) | called by muse, mutect2, varscan2
- CFAP206 | c.255C>T p.V85= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as rs1208566327; called by muse, mutect2, varscan2
- FZD9 | c.867G>A p.A289= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs1275816380; called by muse, mutect2, varscan2
- KRT15 | c.720G>A p.L240= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as rs200579517, COSV54180536; called by muse, mutect2, varscan2
- OR4K14 | c.798C>T p.F266= | Silent (SNP) | VAF 34/133 reads (26%) | called by muse, mutect2, varscan2
- OR52A5 | c.27C>T p.F9= | Silent (SNP) | VAF 74/141 reads (52%) | called by muse, mutect2, varscan2
- RAB44 | c.2160C>A p.L720= | Silent (SNP) | VAF 72/200 reads (36%) | called by muse, mutect2, varscan2
- SLFN5 | c.2457C>T p.L819= | Silent (SNP) | VAF 51/145 reads (35%) | called by muse, mutect2, varscan2
- TTPA | c.618C>G p.V206= | Silent (SNP) | VAF 26/62 reads (42%) | called by muse, mutect2, varscan2
- COPG2 | c.-67C>T | 5'UTR (SNP) | VAF 5/11 reads (45%) | catalogued as rs1563076628, COSV58407586; called by muse, mutect2, varscan2
- GRIPAP1 | c.171+68C>T | Intron (SNP) | VAF 24/45 reads (53%) | called by muse, mutect2, varscan2
- IGF2BP2 | c.240-15053C>T | Intron (SNP) | VAF 24/58 reads (41%) | catalogued as rs747360863, COSV99960276; called by muse, mutect2
- IPO5 | c.-138-34G>A | Intron (SNP) | VAF 18/31 reads (58%) | called by muse, mutect2, varscan2
- KLK3 | c.207-89C>T | Intron (SNP) | VAF 15/39 reads (38%) | catalogued as rs1036333175; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85645C>T | Intron (SNP) | VAF 44/174 reads (25%) | called by muse, mutect2, varscan2
- TTN | c.10360+2531G>T | Intron (SNP) | VAF 20/44 reads (45%) | called by muse, mutect2, varscan2
- WDFY4 | c.-4C>T | 5'UTR (SNP) | VAF 6/86 reads (7%) | catalogued as rs1015660547; called by muse, mutect2
